CPTAC case C3L-02169 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db1f6497-d75d-4911-b1b3-32f97632ca3e

Demographics
Sex at birth: male; Race: white; Year of birth: 1961; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 56.8 years (20,732 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,867 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,867 days (5.1 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 10 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 15; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (6 entries)
- Days to follow up: 399 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 914 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 1,140 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,140 days (3.1 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 82 days.
- Days to follow up: 1,475 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,867 days (5.1 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 55 kg; Height: 174 cm; BMI: 18.17; FEV1 before bronchodilator (% of reference): 78.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 6; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02169-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 53 days; Initial weight: 423 mg; Time between clamping and freezing: 29 minutes; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02169-21: Section location: Left lung; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3L-02169-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 53 days; Initial weight: 484 mg; Time between clamping and freezing: 34 minutes; Time between excision and freezing: 24 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02169-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 53 days; Method of sample procurement: Blood Draw.
